Somatic mutation profile of tumor specimen TCGA-ZB-A96E-01A (aliquot TCGA-ZB-A96E-01A-11D-A428-09) from TCGA case TCGA-ZB-A96E, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 60.5 years (22,092 days).
Specimen TCGA-ZB-A96E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59b0408a-ccb4-45db-ab60-86df80bcbb16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96E-10A (Blood Derived Normal), aliquot TCGA-ZB-A96E-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17a9b243-3dff-4b74-a220-1d44eb53bc3c

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 3, In Frame Ins 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 79/506 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- CATIP | c.181del p.E61Sfs*6 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV99179683; called by mutect2, pindel
- CTCF | c.1999+1G>T p.X667_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV50464417, COSV50506802; called by muse, mutect2, varscan2
- EXOSC10 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV58665820, COSV58668384; called by muse, mutect2, varscan2
- GRIA4 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557011356; called by muse, mutect2, varscan2
- PADI3 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64935217, COSV64935481; called by muse, varscan2
- TP53BP2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771266375, COSV59069190; called by muse, mutect2, varscan2
- ABHD17B | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATG13 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ATG7 | c.1018A>T p.M340L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- BCOR | c.5041_5051del p.R1681Sfs*35 (on ENST00000378444 / NM_001123385.2; = p.R1647Sfs*35 on NM_017745.6) | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by pindel, varscan2*
- DYRK4 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- HCRTR2 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- HRAS | c.36_38dup p.G13dup | In Frame Ins (INS) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- MAGEA3 | c.660A>T p.K220N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- OLFM4 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RAB32 | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RYR1 | c.2754C>A p.N918K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP9X | c.557del p.I186Tfs*36 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- ATG7 | c.1017G>T p.L339= | Silent (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- IPP | c.1665A>T p.S555= | Silent (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- LRRFIP2 | c.435A>T p.L145= | Silent (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- PHRF1 | c.4194C>T p.A1398= (on ENST00000264555 / NM_001286581.2; = p.A1397= on NM_020901.4) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1371524512; called by muse, mutect2, varscan2
- ZNF544 | c.1125T>G p.T375= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
